CPTAC case C3L-04392 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0b1a28a3-bccf-46ef-a723-2b72398cf520

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1937; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 80.8 years (29,515 days); Year of diagnosis: 2018; Days to last known disease status: 190 days; Progression or recurrence: no; Days to last follow up: 190 days.
   Pathology details: Greatest tumor dimension: 3 cm.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 190.

Other clinical attributes
- Weight: 78.47 kg; Height: 177.8 cm; BMI: 24.82.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Cigarettes per day: 20; Tobacco smoking quit year: 1977; Alcohol history: Yes; Alcohol intensity: Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04392-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 106 mg; Time between excision and freezing: 21 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04392-21: Section location: Right Hemisphere; Percent tumor nuclei: 70; Percent necrosis: 5.
- Sample C3L-04392-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
